Somatic mutation profile of tumor specimen BA2356D (aliquot aq-BA2356D) from BEATAML1.0 case 2416, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.0 years (22,997 days).
Specimen BA2356D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc868238-3e10-4868-9c0c-116640326e95.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2985D (Solid Tissue Normal), aliquot aq-BA2985D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ea0cc79-e546-4530-a89d-985bdb548532

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTCRA | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs369843415; called by muse, mutect2, varscan2
- RXFP3 | c.920C>A p.A307E | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs1157944873, COSV57504229, COSV57508376; called by muse, mutect2
- BRINP2 | c.205C>A p.Q69K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.185); called by muse, mutect2
- C8orf34 | c.101C>A p.T34N | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2
- CIART | c.352C>A p.L118M | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); called by muse, mutect2
- DOCK3 | c.5110G>A p.G1704S | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.146); called by muse, mutect2
- ITPR2 | c.2226G>T p.L742F | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.26); called by muse, mutect2
- PIK3R4 | c.254T>C p.L85P | Missense Mutation (SNP) | VAF 24/281 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SKIDA1 | c.1987G>T p.A663S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2
- IRF2BPL | c.429G>T p.P143= | Silent (SNP) | VAF 3/46 reads (7%) | catalogued as rs1293039019; called by muse, mutect2
- MTMR11 | c.1539G>C p.L513= (on ENST00000439741 / NM_001145862.2; = p.L441= on NM_181873.3) | Silent (SNP) | VAF 26/103 reads (25%) | called by muse, mutect2, varscan2
- TUBGCP6 | c.3399C>A p.T1133= | Silent (SNP) | VAF 15/146 reads (10%) | catalogued as COSV99956142; called by muse, mutect2, varscan2
- WNK2 | c.180C>A p.A60= | Silent (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2
- IRX4 | c.408-296C>T | Intron (SNP) | VAF 22/66 reads (33%) | catalogued as rs1245737368; called by muse, mutect2, varscan2
